Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042787-09A.2 (aliquot TARGET-15-SJMPAL042787-09A.2-01D) from TARGET case TARGET-15-SJMPAL042787, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,941 days).
Specimen TARGET-15-SJMPAL042787-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e3bd49-b47f-4efe-97c0-36c7b9085876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042787-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042787-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a78030f-35c9-4d71-98a4-d59cfcddcb55

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 3, 5'Flank 2, Splice Site 1, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.2793G>T p.*931Yext*27 | Nonstop Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV53178881; called by muse, mutect2
- FOXN4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1030853041; called by muse, mutect2, varscan2
- FRMPD4 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs376320353, COSV66212003; called by muse, mutect2, varscan2
- JPH2 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs766295044, COSV65902954; called by muse, mutect2, varscan2
- MSRA | c.336A>T p.K112N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1234527523, COSV57798715; called by muse, mutect2, varscan2
- MYF6 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV57350563; called by muse, mutect2, varscan2
- NCAM2 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs937689487, COSV99034556; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, varscan2
- STXBP5L | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs201266367; called by muse, mutect2, varscan2
- COL16A1 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2
- COPS2 | c.570del p.G191Vfs*5 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by pindel, varscan2
- CSNK2B | c.175+7C>A | Splice Region (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- DYNC1H1 | c.6275C>A p.A2092D | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAT1 | c.9166G>T p.A3056S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD11 | c.404C>A p.A135E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.103); called by muse, varscan2
- NEDD1 | c.1789C>A p.Q597K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, varscan2
- SEL1L | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYDE1 | c.1762C>A p.H588N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP9X | c.5985_5986insCCT p.N1995_V1996insP | In Frame Ins (INS) | VAF 36/89 reads (40%) | called by mutect2, pindel, varscan2
- WDR77 | c.869+1G>T p.X290_splice | Splice Site (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- BAZ1B | c.4143G>T p.T1381= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs782078494, COSV100289529; called by muse, mutect2
- GALNT9 | c.780G>T p.S260= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs369113640, COSV100200871; called by muse, mutect2
- GRPR | c.459C>A p.A153= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV66670170; called by muse, mutect2
- WFIKKN2 | c.963G>A p.T321= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs553573836; called by muse, varscan2
- XRN1 | c.1638A>C p.P546= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- HIF3A | c.27-265C>A | Intron (SNP) | VAF 4/47 reads (9%) | called by mutect2, varscan2
- MAT2B | chr5:163503363 C>A | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- PHB2 | c.293-92A>T | Intron (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2
- STARD13 | c.170-18373G>T | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- ZBTB37 | chr1:173865615 C>A | 5'Flank (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
